Gene-level copy-number profile of tumor specimen TARGET-10-PASWZJ-09A from TARGET case TARGET-10-PASWZJ, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.2 years (1,908 days).
Specimen TARGET-10-PASWZJ-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-ALL-P2.d0bfaca9-31c7-517a-928c-d6d5956d9b42.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-10-PASWZJ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 362 have no estimate.
https://portal.gdc.cancer.gov/files/d5506854-2886-4aef-a20c-d9a2aa2ac630

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 27; copy number 1: 3,972; copy number 2: 55,234; copy number 3: 723; copy number 4: 288; copy number 5: 11; copy number 6: 6.

Homozygous deletions (total copy number 0; autosomes only): 27 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:38,256,337–38,292,078, 6 genes: TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11.
- chr11:5,776,165–5,783,355, 1 gene: OR52N5.
- chr14:22,168,429–22,482,959, 20 genes (within-gene range 0–2): TRAV30, TRAV31, TRAV32, TRAV33, AC244502.1, TRAV26-2, TRAV34, TRAV35, TRAV36DV7, TRAV37, TRAV38-1, TRAV38-2DV8, TRAV39, TRAV40, TRAV41, AC244502.2, AC244502.3, TRDV2, TRDD1, TRDD2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 17 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:135,181,308–135,260,933, 4 genes, copy number 6: MYB, MYB-AS1, MIR548A2, AL023693.1.
- chr6:135,301,568–135,327,965, 2 genes, copy number 6: AL049552.1, AL049552.2.
- chr10:133,430,394–133,523,558, 3 genes, copy number 5: OR6L2P, SCART1, OR7M1P.
- chr10:133,526,259–133,527,513, 1 gene, copy number 5: AL161645.1.
- chr14:97,749,264–98,514,798, 7 genes, copy number 5: LINC02312, AL355097.1, LINC01550, AL163932.1, LINC02295, RN7SL714P, AL132719.1.

Autosomal genes at a single copy (total copy number 1): 1,590. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
